Gene-level copy-number profile of tumor specimen TCGA-BR-8285-01A from TCGA case TCGA-BR-8285, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.1 years (20,849 days).
Specimen TCGA-BR-8285-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2c90bf95-b211-43e6-a1a3-7e0346edcd31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8285-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29b3b078-4704-4865-b980-f31c77a800f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,168; copy number 2: 53,047; copy number 3: 4,494; copy number 25: 2; copy number 28: 29; copy number 29: 3; copy number 30: 1; copy number 39: 24; copy number 45: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8285-01A-11D-2338-01): tumor purity 0.3, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 94 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,699,942–2,391,707, 24 genes, copy number 39 (within-gene range 2–39): MMP23A, CDK11A, AL031282.2, AL031282.1, SLC35E2A, NADK, GNB1, AL109917.1, CALML6, TMEM52, CFAP74, AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr9:452,492–3,053,408, 34 genes, copy number 25–29 (within-gene range 2–29): AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1.
- chr9:4,070,906–4,071,884, 1 gene, copy number 30: AL359095.1.
- chr9:4,781,475–5,776,557, 35 genes, copy number 45 (within-gene range 2–45): AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1.

Autosomal genes at a single copy (total copy number 1): 960. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
